Somatic mutation profile of tumor specimen TCGA-36-2548-01A (aliquot TCGA-36-2548-01A-01D-1526-09) from TCGA case TCGA-36-2548, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.2 years (20,897 days).
Specimen TCGA-36-2548-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 202fe9b6-a6b1-4891-8714-ec577249ca89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2548-10A (Blood Derived Normal), aliquot TCGA-36-2548-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8db03e7-542c-44f3-b2f3-18186198fd80

The open-access MAF lists 56 somatic variants for this specimen: 47 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 38, Silent 9, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD3G | c.205A>T p.K69* | Nonsense Mutation (SNP) | VAF 107/196 reads (55%) | catalogued as rs199676861, CM983819, COSV52675786; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 101/122 reads (83%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- ABCA9 | c.1583A>G p.N528S | Missense Mutation (SNP) | VAF 150/184 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV60629169; called by muse, mutect2, varscan2
- ASH2L | c.361A>T p.T121S | Missense Mutation (SNP) | VAF 94/1178 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV99167017; called by muse, mutect2
- CATSPERB | c.2581C>G p.L861V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV56432104; called by muse, mutect2, varscan2
- CCDC88B | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV100105745; called by muse, mutect2
- CSF3R | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs765312095, COSV58970039; called by muse, mutect2, varscan2
- CTNNA3 | c.2114C>A p.A705D | Missense Mutation (SNP) | VAF 149/690 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65527816; called by muse, mutect2, varscan2
- DBF4 | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 118/210 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55998246; called by muse, mutect2, varscan2
- DNAH8 | c.4832T>A p.V1611E | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100546583; called by muse, mutect2
- EXOC8 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777719915, COSV50479156; called by muse, mutect2, varscan2
- FREM2 | c.4417G>A p.D1473N | Missense Mutation (SNP) | VAF 149/262 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1349614279, COSV54847035; called by muse, mutect2, varscan2
- GATAD1 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV55320104; called by muse, mutect2, varscan2
- HGF | c.866-1G>T p.X289_splice | Splice Site (SNP) | VAF 10/170 reads (6%) | catalogued as COSV55946310; called by muse, mutect2
- INVS | c.1754A>T p.H585L | Missense Mutation (SNP) | VAF 15/558 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52446954, COSV99317962; called by muse, mutect2
- KATNAL1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 43/528 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1339235649, COSV66062649; called by muse, mutect2
- KIF21B | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV59763540; called by muse, mutect2, varscan2
- KLK8 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs747062903, COSV51593277; called by muse, mutect2, varscan2
- KRT10 | c.278G>C p.S93T | Missense Mutation (SNP) | VAF 164/199 reads (82%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.212); catalogued as COSV54090961; called by muse, mutect2, varscan2
- MFSD3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV56742541; called by muse, mutect2, varscan2
- MYF5 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99953357; called by muse, mutect2
- MYOM2 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 184/474 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.599); catalogued as COSV50751343; called by muse, mutect2, varscan2
- NEO1 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 66/73 reads (90%) | SIFT tolerated (0.74); PolyPhen benign (0.067); catalogued as COSV56076390; called by muse, mutect2, varscan2
- NUDCD1 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 23/577 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53455008; called by muse, mutect2
- OR5F1 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 29/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99558820; called by muse, mutect2
- PHF8 | c.2632C>A p.P878T (on ENST00000357988 / NM_001184896.1; = p.P842T on NM_015107.3) | Missense Mutation (SNP) | VAF 53/365 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57686187; called by muse, mutect2, varscan2
- POLR2C | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54673955; called by muse, mutect2, varscan2
- PPM1F | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs780020474, COSV54286004, COSV54286334; called by muse, mutect2, varscan2
- PTPN18 | c.332C>A p.T111N | Missense Mutation (SNP) | VAF 105/341 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1558840955, COSV51560224; called by muse, mutect2, varscan2
- PTPRZ1 | c.5036C>G p.P1679R | Missense Mutation (SNP) | VAF 127/802 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs958191976, COSV66442856; called by muse, mutect2, varscan2
- REG1B | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 47/498 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100521461; called by muse, mutect2
- RNF111 | c.1007+1G>T p.X336_splice | Splice Site (SNP) | VAF 130/170 reads (76%) | catalogued as COSV62088751; called by muse, mutect2, varscan2
- RNF185 | c.483T>A p.A161= | Splice Region (SNP) | VAF 38/384 reads (10%) | catalogued as COSV56736519; called by muse, mutect2, varscan2
- SF3A1 | c.971A>C p.E324A | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99305614; called by muse, mutect2
- SGTB | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 214/238 reads (90%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs774534862, COSV51559722; called by muse, mutect2, varscan2
- SLC35F5 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV55519841; called by muse, mutect2, varscan2
- SLITRK4 | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.566); catalogued as COSV62025521, COSV62025809; called by muse, mutect2, varscan2
- SPEN | c.5983C>T p.P1995S | Missense Mutation (SNP) | VAF 68/101 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1490101809, COSV65366063; called by muse, mutect2, varscan2
- TEAD1 | c.241A>T p.T81S | Missense Mutation (SNP) | VAF 23/479 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV100532673; called by muse, mutect2
- TMC2 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 85/377 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as COSV62656745; called by muse, mutect2, varscan2
- TMEM109 | c.95T>G p.L32W | Missense Mutation (SNP) | VAF 317/596 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV50016256; called by muse, mutect2, varscan2
- TRPC5 | c.1888C>A p.L630I | Missense Mutation (SNP) | VAF 90/393 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.573); catalogued as COSV53299294; called by muse, mutect2, varscan2
- TTC16 | c.1525G>C p.V509L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV60161790; called by muse, mutect2, varscan2
- UTP20 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 230/577 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55382979; called by muse, mutect2, varscan2
- NCOA6 | c.5541_5545del p.A1848Wfs*4 | Frame Shift Del (DEL) | VAF 42/452 reads (9%) | called by mutect2, pindel
- NUP205 | c.4795_4796del p.M1599Vfs*35 | Frame Shift Del (DEL) | VAF 90/472 reads (19%) | called by mutect2, pindel, varscan2
- SERPINI1 | c.971del p.G324Afs*19 | Frame Shift Del (DEL) | VAF 52/139 reads (37%) | called by mutect2, pindel, varscan2
- ARMC4 | c.1791G>A p.S597= | Silent (SNP) | VAF 146/379 reads (39%) | catalogued as rs779015420, COSV59458788; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC148 | c.114A>T p.A38= | Silent (SNP) | VAF 28/488 reads (6%) | catalogued as rs758945687, COSV99321077; called by muse, mutect2
- CSMD2 | c.9945C>T p.G3315= | Silent (SNP) | VAF 102/485 reads (21%) | catalogued as rs755183571, COSV53876779; called by muse, mutect2, varscan2
- GYS1 | c.1899G>T p.G633= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as COSV54404595; called by muse, mutect2, varscan2
- LIN7A | c.237T>C p.N79= | Silent (SNP) | VAF 36/392 reads (9%) | catalogued as rs1488403461, COSV99692480; called by muse, mutect2
- MAN1A2 | c.1353G>T p.G451= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as COSV62980310; called by muse, mutect2, varscan2
- NPY5R | c.924C>T p.H308= | Silent (SNP) | VAF 49/62 reads (79%) | catalogued as rs761031263, COSV58453268; called by muse, mutect2, varscan2
- SENP5 | c.807G>A p.Q269= | Silent (SNP) | VAF 14/270 reads (5%) | catalogued as COSV100052174, COSV60207273; called by muse, mutect2
- ZNF530 | c.1080T>C p.F360= | Silent (SNP) | VAF 61/377 reads (16%) | catalogued as COSV60532211; called by muse, mutect2, varscan2
